Surgical pathology report (de-identified scan), TCGA case TCGA-IG-A97I, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Asterand, specimen TCGA-IG-A97I-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: There is esophagus with ulcerated dense gray rose tumor 3x4 cm in its size. Tissue of stomach 10x7 cm in its size, mucosa is rose plicated.

Microscopic Description: 1) Squamous cell carcinoma, G2 pT2 with expressed inflammatory infiltration.

2)3) In 4 examined paraesophageal lymph nodee no metastasis pathological finding, hyperplasia of follicle.

Diagnosis Details: Tumor Features: Ulcerated, Tumor Extent: Muscularis Propria, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: ESOPHAGUS TISSUE CHECKLIST

Specimen type: Esophagectomy

Tumor site: Thoracic esophagus

Tumor size: 4 x 0 x 3 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Muscularis propria

Lymph nodes: 0/4 positive for metastasis (Paraesophageal nodes 0/4)

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: No

Additional pathologic findings: Lower third - thoracic

Comments: None

ICD-O-3

Carcinoma, squamous cell NOS
807013
Site Esophagus, distal third
C15.5
Lower third of esophagus
C15.5
4/7/14

Reviewed by [initials]	Date Reviewed: 12/14/13	

Source: NCI Genomic Data Commons file 9b84b788-4850-4041-bc7f-6245d3784797 (TCGA-IG-A97I.2AA80697-84EC-49B2-B7DD-BE86A1118388.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).